Somatic mutation profile of tumor specimen TARGET-10-PASMIC-09A (aliquot TARGET-10-PASMIC-09A-01D) from TARGET case TARGET-10-PASMIC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,916 days).
Specimen TARGET-10-PASMIC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 501081c7-5f61-484c-9c9a-5cc20e562e26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASMIC-10A (Blood Derived Normal), aliquot TARGET-10-PASMIC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/111dd75c-3547-413b-b6e1-2764c11b3cbf

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 5, Silent 3, Frame Shift Ins 3, RNA 2, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMK2G | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59481734; called by muse, mutect2, varscan2
- CHMP4B | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV54135930; called by muse, mutect2, varscan2
- EIF2S3 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV53406539; called by muse, mutect2
- ELAVL2 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 55/61 reads (90%) | SIFT tolerated (0.17); PolyPhen benign (0.285); catalogued as COSV56361433; called by muse, mutect2, varscan2
- GLYR1 | c.48_49insTTCT p.G17Ffs*13 | Frame Shift Ins (INS) | VAF 35/91 reads (38%) | catalogued as COSV52167941; called by mutect2, pindel, varscan2
- IGFBP6 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 33/55 reads (60%) | catalogued as rs770394224, COSV100037124, COSV56857324; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- POLR2A | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59494229; called by muse, mutect2
- STT3A | c.1031C>G p.P344R | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67064677; called by muse, mutect2, varscan2
- USP7 | c.1753_1754insGG p.D585Gfs*6 | Frame Shift Ins (INS) | VAF 20/42 reads (48%) | called by mutect2, varscan2
- USP7 | c.1752delinsTGG p.D585Gfs*6 | Frame Shift Ins (INS) | VAF 26/51 reads (51%) | called by mutect2*, pindel, varscan2*
- CHMP4B | c.309C>G p.T103= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99459713; called by muse, mutect2, varscan2
- GABRG2 | c.228A>T p.G76= | Silent (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
- UBR4 | c.810C>A p.I270= | Silent (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
- BARX2 | c.488+116G>A | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- HSBP1L1 | c.118+189G>A | Intron (SNP) | VAF 6/10 reads (60%) | catalogued as rs1382049178; called by muse, mutect2
- NBAT1 | n.323_324insTCGCGGGA | RNA (INS) | VAF 44/113 reads (39%) | called by mutect2, pindel, varscan2
- PIPSL | n.108del | RNA (DEL) | VAF 22/73 reads (30%) | called by mutect2, pindel, varscan2
- RASGRF2 | c.1390+275C>A | Intron (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- SCAF11 | c.842-35T>A | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2
- TMCO5A | c.-3A>G | 5'UTR (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- TNNI3K | c.1667+39G>A | Intron (SNP) | VAF 13/21 reads (62%) | catalogued as rs200735592; called by muse, mutect2, varscan2
